Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A1AW, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A1AW-01A (Primary Tumor).

ICD-0-3

Carcinoma, infiltrating duct, NOS 8500/3

Path Site Code: breast, upper inner quadrant C50.2

12/21/10

CQCF Site: breast, NOS C50.9

Final Diagnosis

Breast, left upper inner quadrant, lumpectomy: Infiltrating ductal carcinoma, with medullary like features, Nottingham grade III (of III), [tubules 3/3, nuclei 3/3, mitoses 2/3; Nottingham score 8/9], forming a 2.7 x 2.5 x 2.0 cm yellow-tan, somewhat circumscribed, sclerotic mass [AJCCpT2]. Ductal carcinoma in situ is absent. Angiolymphatic invasion is absent. All surgical resection margins, after re-excision of the deep and medial inferior margins, are negative for tumor (minimum tumor free margin, 0.8 cm, deep margin).

Lymph node, left axillary, sentinel biopsy: A single (1) left axillary sentinel lymph node is negative for tumor, confirmed by cytokeratin (AE1/AE3) immunostains.

ER/PR and Her2/neu have been ordered on paraffin-embedded tissue.

Case is [circle]:	DISQUALIFIED / DISQUALIFIED	

Source: NCI Genomic Data Commons file 8fb7733b-5f20-4e83-a1c4-16a5920e3f56 (TCGA-AR-A1AW.BB485405-199C-48C7-96D7-8C315DEA66B4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).